Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2RK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2RK-01A (Primary Tumor).

[page 1 of 3]
Department of Laboratories
PATHOLOGY REPORT
Tissue Examination

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED]
DOB: [REDACTED] (Age: [REDACTED])
Sex: F
Submitted By: [REDACTED]

Client:
Location:
Billing #:
Encounter #:
Copy To:

Accession #:
Collected:
Received:
orted:

Diagnosis

A. Left pelvic lymph nodes, dissection
- Nineteen benign lymph nodes (0/19).

B. Right pelvic lymph nodes, dissection
- Eight benign lymph nodes (0/8).

C. Cervix, uterus, upper vagina and bilateral adnexa, radical hysterectomy
- Invasive squamous cell carcinoma of uterine cervix. See checklist below for details.

Tumor type:

- Invasive squamous cell carcinoma of uterine cervix, non-keratinizing.

Histologic grade:

- Moderately to poorly differentiated.

Tumor site:

- Involving all quadrants of cervix.

Tumor size:

- 3.3 cm in largest measurement based on the number of blocks involved.

Maximum depth of invasion:

- 1.1 cm (slide C24)

Tumor multicentricity

- Not identified.

In situ carcinoma:

In situ carcinoma is also identified.

Vascular invasion:

- No definite vascular invasion is identified.

Vaginal extension:

- In situ squamous cell carcinoma involving at least 12 to 3 and 6 to 9 o'clock areas.

Uterine corpus extension:

- Not identified.

ICD-O-3
carcinoma, squamous cell,
nonkeratinizing, NOS 8074/3
Site: cervix, NOS C53.9 lw
9/8/11

[page 2 of 3]
Surgical Pathology Report

Parametrial involvement

- No parametrial involvement is identified.
- Endometriosis.

Surgical margins:

- In situ carcinoma involving vaginal margin.

Endometrium:

- Atrophic.

Myometrium:

- Unremarkable.

Adnexae:

- Unremarkable.

Lymph nodes:

- Two benign periuterine lymph nodes.
- See also parts A & B.

AJCC staging:

- pT1b1N0Mx.

I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material) and that I have reviewed and approved this report.

Electronically Signed Out By

Clinical History

Cervical cancer

Gross Description

A. Specimen is received in formalin with proper patient identification labeled "left pelvic lymph node" and consists of multiple pieces of fatty tissue measuring 7 x 6 x 2.5 cm. Multiple lymph nodes are identified ranging in size from 0.4-1.5 cm. Lymph nodes are submitted in 10 cassettes.

1-5- Lymph nodes

6- One lymph node bisected

7- One lymph node bisected

8- One lymph node bisected

9-10- One lymph node bisected

B. Specimen is received in formalin with proper patient identification labeled "right pelvic lymph node" and consists of multiple pieces of fatty tissue measuring in 7 x 6 x 2 cm. Multiple lymph nodes are identified ranging in size from 0.4 – 3.6 cm. Lymph nodes are submitted in 5 cassettes.

1- Lymph nodes

2- One lymph node bisected

[page 3 of 3]
Surgical Pathology Report

- 3- One lymph node bisected
- 4-5- One lymph node bisected

C. The specimen is received fresh, with proper patient identification, and is labeled cervix, uterus, upper vagina and bilateral adnexa. It consists of a uterus measuring 9 cm from cervix to fundus, 4 cm from cornu to cornu and 2.5 cm from anterior to posterior with attached cervix measuring 3 x 3 cm, bilateral ovaries measuring 2.5 x 2.0 x 1.2 cm (left) and 2.5 x 2.1 x 1.0 cm (right), bilateral fallopian tubes measuring 5.0 x 0.5 cm (left) and 4.5 x 0.5 cm (right), parametria measuring 3.5 x 1.5 x 1.0 (left) and 3.5 x 3.0 x 1.0 cm (right) and vaginal cuff measuring 1.0 cm. Entire specimen weighs 92.3 grams. The parametrial tissue and resection margins are inked black. No grossly identifiable tumor is seen. Endometrium, myometrium, uterine serosa and both adnexa are unremarkable. The cervix is amputated and entirely submitted in a cone fashion. Representative sections of the remaining specimen are submitted, including vaginal margins en face.

Summary of sections:

- 1-6- Vaginal cuff margin en face
- 7-8- Right parametria
- 9-10- Left parametria
- 11-12- Cervix, 12-3 o'clock position
- 13-14- Cervix, 3-6 o'clock position
- 15-19- Cervix, 6-9 o'clock position
- 20-24- Cervix, 9-12 o'clock position
- 25- Representative sections of left ovary and tube
- 26- Representative sections of right ovary and tube
- 27- Anterior endometrium
- 28- Posterior endometrium

This specimen is grossed by

ICD-9(s) 180.9 233.31 229.0
SNOMED Codes: A: T08000 T08600
B: T08000 T08600
C: M80703 P1100 T81000 T82000 T83000 T86920
D: M80723 T83000
F: M80001
G: M80001
I: M80001
J: M80102
K: T40000
M: T81000
O: T86400
P: T00100
Q: T84000
R: T85000
T: T08000
88309, 88307(2)

Source: NCI Genomic Data Commons file 367c12f6-722d-4519-a6d8-22d3d33ff294 (TCGA-EK-A2RK.53039912-13F8-4EB8-B8DD-39B39F2AE486.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).